Surgical pathology report (de-identified scan), TCGA case TCGA-LB-A7SX, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Candler, specimen TCGA-LB-A7SX-01A (Primary Tumor).

[page 1 of 3]
RUN DATE: [REDACTED]
RUN TIME: [REDACTED]
RUN USER: [REDACTED]

Specimen Inquiry

PAGE 1

PATIENT: [REDACTED]

ACCT #: [REDACTED]

LOC: [REDACTED]

AGE/SX: /F

ROOM: [REDACTED]

REG DR: [REDACTED]

DOB: [REDACTED]

BED: [REDACTED]

STATUS: [REDACTED]

SPEC #:

RECD:

STATUS:

PERFORMED AT [REDACTED]

COLL:

TIME IN FORMALIN:

hrs.

COLD ISCHEMIA TIME:

mins.

CLINICAL INFORMATION:

Pre-Op Diagnosis:

Remarks:

- Specimen(s):
- A. Pancreatic duct margin
- B. Common duct margin
- C. Whipple contents

MICROSCOPIC DIAGNOSIS

- A. PANCREATIC DUCT MARGIN:
- SQUAMOUS METAPLASIA
- CHRONIC INFLAMMATION
- NO EVIDENCE OF MALIGNANCY
- B. COMMON DUCT MARGIN:
- CHRONIC INFLAMMATION
- NO EVIDENCE OF MALIGNANCY
- C. WHIPPLE CONTENTS:
- ADENOCARCINOMA
- SEE COMMENT FOR DETAILS

ICD-O-3

Adenocarcinoma duct NOS 8500/3

Site Pancreas head C25.0

9/10/10/13

COMMENT(S)

COLLEGE OF AMERICAN PATHOLOGISTS' PROTOCOL FOR EXAMINATION OF SPECIMENS WITH CARCINOMA OF THE EXOCRINE PANCREAS, BASED ON AJCC/UICC TNM, 7TH EDITION

The following classification should be adjusted based on additional clinical information.

Specimen: Stomach, duodenum, pancreas
Procedure: Whipple
Tumor Site: Pancreatic head
Tumor Size: 2.5 cm
Histologic Type: Ductal adenocarcinoma
Histologic Grade: Grade 2
Microscopic Tumor Extension: Tumor invades ampulla of Vater, duodenal wall, peripancreatic soft tissue
Margins: Margins involved by invasive carcinoma
Treatment Effect: No prior treatment
Lymph-Vascular Invasion: Present

** CONTINUED ON NEXT PAGE **

[page 2 of 3]
RUN DATE:
RUN TIME:
RUN USER:

Specimen Inquiry

PAGE 2

SPEC #: PATIENT: (Continued)

COMMENT(S)

(Continued)

Perineural Invasion: Present
Pathologic Staging: Primary Tumor: pT3
Regional Lymph Nodes: pN1
Number found: 26
Number examined: 26
Number involved: 7
Distant Metastasis: Not applicable
Additional Pathologic Findings: Pancreatic intraepithelial neoplasia III
Acute and chronic pancreatitis
Pancreatic abscess

GROSS DESCRIPTION:

A. The specimen is labeled "pancreatic duct margin". The specimen consist of two reddish tan pieces of tissue. I don't see any staple lines in the one, it looks like it may be clot or maybe a lymph node. The specimen is entirely frozen in one block.

B. The specimen is labeled "common duct margin". The specimen consist of a single gray membranous red piece of tissue measuring about 1 x 0.6 cm, entirely frozen in block B.

C. The specimen is labeled "whipple contents". The specimen is received in the unfixed state in the operating room and consists of a single specimen consisting of stomach. The lesser curvature measures 6.5 cm, greater curvature 10.5 cm, proximal staple line measures 7 cm. The serosal surface of the stomach is grossly unremarkable. The duodenum and small intestine measures 20 cm in length. The distal end is stapled closed. The surface of the small intestine demonstrates some hemorrhagic adhesions along the anterior surface. The gastric duodenal mucosa is opened revealing a small amount of mucoid blood. The attached pancreas measures 6 x 4.7 x 3.5 cm. One long staple line is running across the edge of the specimen. Some blue ink is placed along the uncinate process. A second smaller 1.3 cm staple line is present in the area of the bile duct. I could probe the ampulla about 1.5 cm then becomes stenotic. Representative sections of the unremarkable stomach and gastric lymph nodes submitted in cassette C1. The ampulla is probed through the specimen, sections of the ampulla and suspicious tumor in the pancreas in the area submitted for tumor banking submitted in cassette C2. This is a section along the length of the duct. One smear imprint is made of the suspicious area and this area is then sampled for tumor banking. Two additional parallel sections are submitted in cassettes C3 and C4. Tumor estimation size on cross sectioning is 2.2 x 2.5 x 2.0 cm. Representative sections of tumor submitted through cassettes C10. One section including the inked margin. There is a small blue suture at one margin submitted in cassette C7. Suspected lymph node submitted in cassette C8. One complete cross section including an area where the tissue is submitted for tumor banking submitted in cassettes C11, 12 and 13. One additional cross section submitted in cassettes 14 through 17.

MICROSCOPIC DESCRIPTION:

The invasive adenocarcinoma originates from in situ carcinoma in the pancreatic duct and extends into the wall of the duodenum and the mucosa of the ampulla. The tumor also extends outward outside the pancreas into the surrounding fibroadipose vascular connective

** CONTINUED ON NEXT PAGE **

[page 3 of 3]
RUN DATE:
RUN TIME:
RUN USER:

Specimen Inquiry

PAGE 3

SPEC #

PATIENT:

(Continued)

MICROSCOPIC DESCRIPTION: (Continued)

tissue and inked margins. The tumor measures 2 mm from the uncinate process margin. There is a fair amount of acute and chronic inflammation with extensive squamous metaplasia of the pancreatic duct. This is also associated with the acute pancreatitis with abscess formation.

INTRAOPERATIVE CONSULTATION:
FROZEN SECTION:

A. PANCREATIC DUCT MARGIN:

-

B. COMMON DUCT MARGIN:

-

CYTOLOGY SMEAR:

C. WHIPPLE CONTENTS:

- ADENOCARCINOMA

- TUMOR RETRIEVED FOR TUMOR BANKING

INITIAL IMPRESSION:
IMMEDIATE ASSESSMENT:

A. PANCREATIC DUCT MARGIN:

- NO EVIDENCE OF MALIGNANCY

B. COMMON DUCT MARGIN:

- NO EVIDENCE OF MALIGNANCY

PHOTO DOCUMENTATION

Image

Signed ____ (signature on file) ____

** END OF REPORT **

Source: NCI Genomic Data Commons file 374fe524-9fd7-42b5-a215-b86189fd67e7 (TCGA-LB-A7SX.24F140DA-8E12-429B-9699-525CD1F3A045.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).